Somatic mutation profile of tumor specimen TCGA-DX-A3U8-01A (aliquot TCGA-DX-A3U8-01A-11D-A29N-09) from TCGA case TCGA-DX-A3U8, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 43.1 years (15,751 days).
Specimen TCGA-DX-A3U8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 911c5842-1d29-4895-a94a-e97cb337fa4c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A3U8-10A (Blood Derived Normal), aliquot TCGA-DX-A3U8-10A-01D-A29N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e2d4bb9d-6ba3-414b-b122-6e75296ab09a

The open-access MAF lists 34 somatic variants for this specimen: 24 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 20, Silent 10, Nonsense Mutation 2, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3C3 | c.110A>T p.K37M | Missense Mutation (SNP) | VAF 8/60 reads (13%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.357); catalogued as COSV63550964, COSV63551270; called by muse, mutect2
- DNAH7 | c.7454G>A p.R2485H | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs766897304, COSV56773922; called by muse, mutect2
- ERBB4 | c.1916C>T p.T639M | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs532377012, COSV53542123; called by muse, mutect2, varscan2
- F5 | c.5520C>A p.H1840Q | Missense Mutation (SNP) | VAF 3/51 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.849); catalogued as COSV100888967; called by muse, mutect2
- GAS2L1 | c.1568A>C p.E523A | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.026); catalogued as COSV99329422; called by muse, mutect2, varscan2
- GPSM1 | c.1914G>C p.Q638H | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.322); catalogued as rs1157159465; called by muse, mutect2, varscan2
- H4C3 | c.203G>C p.R68P | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.173); catalogued as rs778987751, COSV58090178; called by muse, mutect2, varscan2
- NSMAF | c.228+2T>C p.X76_splice | Splice Site (SNP) | VAF 10/50 reads (20%) | catalogued as COSV99232453; called by muse, mutect2, varscan2
- PCDHB14 | c.337C>G p.P113A | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.727); catalogued as rs1310907174, COSV53390888; called by muse, mutect2, varscan2
- PGM5 | c.281G>C p.G94A | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV101123377; called by muse, varscan2
- PRLHR | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs778904375, COSV53304803; called by muse, mutect2, varscan2
- PTPN11 | c.1070C>T p.T357M | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV61009672; called by muse, mutect2, varscan2
- QRICH2 | c.3313C>T p.Q1105* | Nonsense Mutation (SNP) | VAF 12/59 reads (20%) | catalogued as COSV99428874; called by muse, mutect2, varscan2
- RAPGEF1 | c.2617G>A p.E873K | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64699471; called by muse, mutect2, varscan2
- SIPA1L1 | c.1375G>A p.G459R | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV62173252; called by muse, mutect2, varscan2
- TRIM11 | c.1304C>T p.S435L | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.828); catalogued as rs753855545, COSV52856847, COSV99488628; called by muse, mutect2, varscan2
- BBS9 | c.1579T>G p.F527V (on ENST00000242067 / NM_001348036.1; = p.F487V on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.011); called by muse, mutect2
- CFAP53 | c.517C>T p.Q173* | Nonsense Mutation (SNP) | VAF 7/25 reads (28%) | called by muse, mutect2, varscan2
- KIF15 | c.130G>C p.D44H | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- LEO1 | c.1825G>C p.D609H | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LIG4 | c.1492T>C p.S498P | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- LRBA | c.484T>C p.Y162H | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- OR10G7 | c.527A>T p.Y176F | Missense Mutation (SNP) | VAF 42/170 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- PRKCA | c.1534del p.Y512Ifs*61 | Frame Shift Del (DEL) | VAF 11/64 reads (17%) | called by mutect2, pindel, varscan2
- ATP10A | c.2922C>T p.I974= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as rs765325556; called by muse, mutect2, varscan2
- GUCY1A1 | c.1755C>T p.G585= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as rs571318059, COSV56651192; called by muse, mutect2, varscan2
- HSD3B2 | c.627G>T p.G209= | Silent (SNP) | VAF 11/68 reads (16%) | called by muse, mutect2, varscan2
- ITGAL | c.429G>T p.G143= | Silent (SNP) | VAF 16/61 reads (26%) | called by muse, mutect2, varscan2
- MCC | c.1755G>A p.L585= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as COSV56727001; called by muse, mutect2, varscan2
- PCDHGA9 | c.1878G>A p.V626= | Silent (SNP) | VAF 20/113 reads (18%) | catalogued as rs775106144; called by muse, mutect2, varscan2
- PLCE1 | c.4008C>T p.C1336= | Silent (SNP) | VAF 32/84 reads (38%) | catalogued as rs1173047831; called by muse, mutect2, varscan2
- PLXDC1 | c.1302C>T p.V434= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV100195423; called by muse, mutect2, varscan2
- RNASEL | c.2088T>C p.F696= | Silent (SNP) | VAF 16/83 reads (19%) | called by muse, mutect2, varscan2
- SHISA2 | c.369C>T p.S123= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs139266835; called by muse, mutect2, varscan2
